Somatic mutation profile of tumor specimen C3L-03727-01 (aliquot CPT0225730006) from CPTAC case C3L-03727, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.4 years (26,097 days).
Specimen C3L-03727-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc336bd-ca26-4947-ad8f-a60d7c8e3b5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03727-31 (Blood Derived Normal), aliquot CPT0226070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77dda98e-a42a-4ae8-9fb8-d230530f551f

The open-access MAF lists 104 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Intron 6, 3'UTR 4, RNA 3, Splice Site 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2696/3079 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 28/158 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs769734277; called by muse, mutect2, varscan2
- ADGRE1 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs778436226, COSV51672839; called by muse, mutect2, varscan2
- AMER1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as rs750971248, COSV57660957; called by muse, mutect2, varscan2
- ASIC4 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs777793535, COSV61731810; called by muse, mutect2, varscan2
- AZGP1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.864); catalogued as rs759231305, COSV52797492; called by muse, mutect2, varscan2
- BCAS3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV66771521; called by muse, mutect2, varscan2
- BDKRB2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766976697, COSV60016597; called by muse, mutect2, varscan2
- C9orf43 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1281857705; called by muse, mutect2, varscan2
- CAPN8 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1469115341; called by muse, mutect2, varscan2
- CCDC158 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 97/258 reads (38%) | catalogued as rs755862671, COSV66356514; called by muse, mutect2, varscan2
- CEP76 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1377133147; called by muse, mutect2, varscan2
- CXCR1 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473614327; called by muse, mutect2, varscan2
- CXCR3 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1415409982; called by muse, mutect2, varscan2
- HCRTR2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.727); catalogued as rs768933844; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- LTBP4 | c.4691G>A p.R1564H (on ENST00000308370 / NM_001042544.1; = p.R1527H on NM_003573.2) | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV52584910; called by muse, mutect2, varscan2
- MAST1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52254101; called by muse, mutect2, varscan2
- MEGF8 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748576204; called by muse, mutect2, varscan2
- MYO19 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.072); catalogued as rs373120920; called by muse, mutect2, varscan2
- NCBP2 | c.60C>A p.Y20* | Nonsense Mutation (SNP) | VAF 124/337 reads (37%) | catalogued as COSV58317293; called by muse, mutect2, varscan2
- NR2C1 | c.1712A>G p.K571R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs532594408; called by muse, mutect2, varscan2
- NR4A3 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs755566389, COSV58246594; called by muse, mutect2, varscan2
- OR4K13 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149397731; called by muse, mutect2, varscan2
- PABPC3 | c.1391C>A p.S464Y | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as COSV55807287; called by muse, varscan2
- SERPINB3 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs371529315, COSV99380028; called by muse, mutect2, varscan2
- SERPINF2 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 163/490 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.498); catalogued as rs779579819, COSV60664898; called by muse, mutect2, varscan2
- SI | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411686113, COSV52267354, COSV52278522; called by muse, mutect2, varscan2
- SIPA1L1 | c.3677A>C p.N1226T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.037); catalogued as rs745996619; called by muse, mutect2, varscan2
- SLC1A6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs996260256, COSV55667680; called by muse, mutect2, varscan2
- SLC35F3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1033407677; called by muse, mutect2, varscan2
- SLC44A4 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs745490493, COSV57666350; called by muse, mutect2, varscan2
- SMARCC2 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1356415853, COSV57217119; called by muse, mutect2, varscan2
- STAT5A | c.1775+1G>A p.X592_splice | Splice Site (SNP) | VAF 229/544 reads (42%) | catalogued as COSV99069309; called by muse, mutect2, varscan2
- TBL1X | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV54277684; called by muse, mutect2, varscan2
- UNC79 | c.3725C>T p.S1242F (on ENST00000393151 / NM_001346218.2; = p.S1065F on NM_020818.5) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56401670; called by muse, mutect2, varscan2
- ARHGAP44 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CDH8 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, varscan2
- CNKSR2 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL4A5 | c.4743C>G p.I1581M | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CUL4B | c.924G>C p.L308F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX1 | c.4301C>T p.A1434V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); called by mutect2, varscan2
- DEPDC5 | c.2771C>T p.S924L (on ENST00000400246; = p.S993L on NM_014662.5) | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FANCB | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- FANCB | c.2210T>C p.I737T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- GABRG1 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- GAPVD1 | c.3465C>T p.D1155= (on ENST00000394104; = p.D1164= on NM_015635.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- GRIK2 | c.170T>G p.F57C | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRX4 | c.1505C>A p.A502D | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KIF1B | c.3011G>C p.G1004A (on ENST00000377086 / NM_001365952.1; = p.G958A on NM_015074.3) | Missense Mutation (SNP) | VAF 284/712 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, varscan2
- KLRG2 | c.833T>G p.V278G | Missense Mutation (SNP) | VAF 60/428 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- LANCL3 | c.580A>C p.T194P | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- NSUN7 | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDZD2 | c.7595C>T p.P2532L | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRSS38 | c.910del p.A304Lfs*13 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel, varscan2
- RYR2 | c.8437-2A>T p.X2813_splice | Splice Site (SNP) | VAF 111/321 reads (35%) | called by muse, mutect2, varscan2
- SCYL1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC6A14 | c.1516T>A p.F506I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC9A4 | c.1782C>G p.D594E | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLITRK6 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMARCA2 | c.1553T>C p.I518T | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TLE5 | c.97T>A p.F33I | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHB | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WHRN | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACE | c.798C>T p.Y266= | Silent (SNP) | VAF 107/292 reads (37%) | catalogued as rs121912704, CM053092; called by muse, mutect2, varscan2
- ANO6 | c.1194A>G p.R398= | Silent (SNP) | VAF 29/275 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.3849C>T p.Y1283= | Silent (SNP) | VAF 54/379 reads (14%) | called by muse, mutect2, varscan2
- BIN2 | c.438C>T p.L146= | Silent (SNP) | VAF 60/364 reads (16%) | catalogued as rs78442656, COSV99909307; called by muse, mutect2, varscan2
- CAMSAP1 | c.804G>A p.L268= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2
- CHAF1A | c.2736C>T p.G912= | Silent (SNP) | VAF 84/316 reads (27%) | catalogued as rs745730810, COSV100011169; called by muse, mutect2, varscan2
- ICAM1 | c.189G>A p.P63= | Silent (SNP) | VAF 68/482 reads (14%) | catalogued as rs370020996; called by muse, mutect2, varscan2
- IGF2BP2 | c.585G>A p.P195= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs746680034, COSV60482947; called by muse, mutect2, varscan2
- IL36RN | c.42G>A p.S14= | Silent (SNP) | VAF 130/370 reads (35%) | catalogued as rs200623658; called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 95/781 reads (12%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- KIF2B | c.546C>T p.N182= | Silent (SNP) | VAF 38/258 reads (15%) | catalogued as rs760865719, COSV52135960; called by muse, mutect2, varscan2
- MAPK11 | c.942C>T p.P314= | Silent (SNP) | VAF 103/313 reads (33%) | catalogued as rs201281541, COSV99299264; called by muse, mutect2, varscan2
- MBTPS2 | c.609T>C p.D203= | Silent (SNP) | VAF 66/231 reads (29%) | called by muse, mutect2, varscan2
- MGMT | c.525G>A p.P175= (on ENST00000306010; = p.P144= on NM_002412.5) | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs368921475; called by muse, mutect2, varscan2
- NLRP11 | c.1014C>T p.V338= | Silent (SNP) | VAF 38/317 reads (12%) | catalogued as rs1455149403, COSV64088202; called by muse, mutect2, varscan2
- NOS1 | c.1974C>T p.S658= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs758404786, COSV57612475; called by muse, mutect2, varscan2
- OTUD5 | c.144C>T p.G48= | Silent (SNP) | VAF 127/351 reads (36%) | called by muse, varscan2
- OTUD5 | c.96C>T p.R32= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1278680247; called by muse, varscan2
- OVGP1 | c.1662T>A p.T554= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- PSG8 | c.177C>G p.P59= | Silent (SNP) | VAF 45/364 reads (12%) | catalogued as rs1219105523; called by muse, mutect2, varscan2
- SLC5A2 | c.312C>T p.F104= | Silent (SNP) | VAF 80/360 reads (22%) | catalogued as rs763860436; called by muse, mutect2, varscan2
- SPAG11B | c.219C>T p.H73= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as rs767076314; called by muse, mutect2, varscan2
- ZAN | c.5688C>T p.S1896= | Silent (SNP) | VAF 41/332 reads (12%) | catalogued as rs144009891; called by muse, mutect2, varscan2
- AC245884.12 | n.38C>T | RNA (SNP) | VAF 54/500 reads (11%) | catalogued as rs775191294; called by muse, mutect2, varscan2
- APEX1 | c.*30A>T | 3'UTR (SNP) | VAF 46/347 reads (13%) | called by muse, mutect2, varscan2
- CYP2A7P2 | n.279G>A | RNA (SNP) | VAF 31/185 reads (17%) | catalogued as rs542601095; called by muse, mutect2, varscan2
- DMKN | c.1239+307C>T | Intron (SNP) | VAF 51/185 reads (28%) | catalogued as rs374116395; called by muse, mutect2, varscan2
- FMR1 | c.*509T>A | 3'UTR (SNP) | VAF 18/156 reads (12%) | called by muse, varscan2
- FMR1 | c.*590A>G | 3'UTR (SNP) | VAF 24/142 reads (17%) | called by muse, varscan2
- HNRNPA1 | c.-30A>G | 5'UTR (SNP) | VAF 37/268 reads (14%) | catalogued as rs766253242; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2047G>T | Intron (SNP) | VAF 124/323 reads (38%) | called by muse, varscan2
- MS4A12 | c.276+37T>A | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- MYH11 | c.*108C>T | 3'UTR (SNP) | VAF 66/294 reads (22%) | called by muse, mutect2, varscan2
- PKD1 | c.7864-35T>C | Intron (SNP) | VAF 110/568 reads (19%) | called by muse, mutect2, varscan2
- RBM3 | chrX:48574699 C>T | 5'Flank (SNP) | VAF 37/213 reads (17%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1523C>T | RNA (SNP) | VAF 95/304 reads (31%) | catalogued as rs376964572; called by muse, mutect2, varscan2
- STK3 | c.352-15539C>G | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- TMPRSS11F | c.1015+1867G>A | Intron (SNP) | VAF 26/149 reads (17%) | catalogued as COSV100678497; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777788 G>A | 5'Flank (SNP) | VAF 112/365 reads (31%) | called by muse, mutect2, varscan2
